Somatic mutation profile of tumor specimen MP2PRT-PAPASU-TBP1-A (aliquot MP2PRT-PAPASU-TBP1-A-1-0-D-A83L-36) from MP2PRT case MP2PRT-PAPASU, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Precursor cell lymphoblastic leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.8 years (1,762 days).
Specimen MP2PRT-PAPASU-TBP1-A: Sample type: Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Whole Blood; Biospecimen anatomic site: Blood; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f852a910-8e34-4aaf-a880-23420b8fad3b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAPASU-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAPASU-NB1-A-1-0-D-A83L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0ace59ef-fd0f-410b-a526-227b77c7aba5

The open-access MAF lists 22 somatic variants for this specimen: 20 protein-altering or splice-affecting, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 15, Frame Shift Ins 2, Nonsense Mutation 2, Intron 2, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 118/312 reads (38%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.339); catalogued as rs121913237, COSV54736383, COSV54736555, COSV54736974; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PTPN11 | c.1529A>T p.Q510L | Missense Mutation (SNP) | VAF 199/412 reads (48%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as CM043070, CM052358, COSV61008620; called by muse, mutect2, varscan2
- ARFGEF2 | c.3656G>A p.R1219H | Missense Mutation (SNP) | VAF 163/333 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs769842728, COSV100904280; called by muse, mutect2, varscan2
- DACT2 | c.905C>T p.S302L | Missense Mutation (SNP) | VAF 183/393 reads (47%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as rs1000054867, COSV64693009; called by muse, mutect2, varscan2
- EEF1G | c.220G>A p.A74T | Missense Mutation (SNP) | VAF 118/239 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as rs761237813; called by muse, mutect2, varscan2
- PAX5 | c.293A>T p.K98I | Missense Mutation (SNP) | VAF 166/1538 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV100814049; called by muse, mutect2, varscan2
- THBS2 | c.1228G>A p.V410I | Missense Mutation (SNP) | VAF 218/455 reads (48%) | SIFT tolerated (0.3); PolyPhen benign (0.435); catalogued as rs144973525; called by muse, mutect2, varscan2
- TMPRSS11F | c.436A>T p.I146F | Missense Mutation (SNP) | VAF 85/214 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.506); catalogued as rs1386722055; called by muse, mutect2, varscan2
- WBP1L | c.110A>G p.N37S | Missense Mutation (SNP) | VAF 10/264 reads (4%) | SIFT tolerated (0.87); PolyPhen benign (0.027); catalogued as rs1206383673; called by muse, mutect2
- CDK5 | c.844C>T p.Q282* | Nonsense Mutation (SNP) | VAF 88/135 reads (65%) | called by muse, mutect2, varscan2
- CFAP54 | c.3692G>T p.G1231V | Missense Mutation (SNP) | VAF 99/203 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- GRAMD1A | c.552_553insCT p.D185Lfs*21 | Frame Shift Ins (INS) | VAF 133/320 reads (42%) | called by mutect2, pindel, varscan2
- LRRK2 | c.2061G>C p.K687N | Missense Mutation (SNP) | VAF 11/194 reads (6%) | SIFT tolerated (0.36); PolyPhen benign (0.135); called by muse, mutect2
- RIPK4 | c.1524C>A p.N508K (on ENST00000352483; = p.N460K on NM_020639.3) | Missense Mutation (SNP) | VAF 165/362 reads (46%) | SIFT tolerated (0.09); PolyPhen benign (0.324); called by muse, mutect2, varscan2
- ROR1 | c.1551G>A p.W517* | Nonsense Mutation (SNP) | VAF 26/428 reads (6%) | called by muse, mutect2
- RORC | c.306G>T p.K102N | Missense Mutation (SNP) | VAF 102/202 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- SETD2 | c.6365_6366insTCCTCG p.R2122_K2123insPR | In Frame Ins (INS) | VAF 137/346 reads (40%) | called by mutect2, pindel, varscan2
- SPEN | c.6750dup p.A2251Rfs*10 | Frame Shift Ins (INS) | VAF 178/481 reads (37%) | called by mutect2, pindel, varscan2
- SYCE1 | c.683G>A p.G228E (on ENST00000343131 / NM_001143764.3; = p.G192E on NM_130784.3) | Missense Mutation (SNP) | VAF 99/251 reads (39%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- USH2A | c.5179C>A p.L1727I | Missense Mutation (SNP) | VAF 65/150 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- OBSCN | c.18662-2978G>A | Intron (SNP) | VAF 135/268 reads (50%) | called by muse, mutect2, varscan2
- TTN | c.34354+589G>A | Intron (SNP) | VAF 149/308 reads (48%) | catalogued as rs757573453, COSV60392222; called by muse, mutect2, varscan2
